Surgical pathology report (de-identified scan), TCGA case TCGA-55-6981, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-6981-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

Not for Permanent Storage in Medical Records / Not Valid for Signing

Patient
MRN
Date of Service
Performing Facility
Ordering Provider
Result Provider
Report Name

Requested by [REDACTED]

[REDACTED]
Surgical Report

[REDACTED]

SURGICAL PATHOLOGY REPORT

PROCEDURE DATE: [REDACTED]

===== SPECIMEN DESCRIPTION: =====

- A. AORTOPULMONARY WINDOW LYMPH NODE
- B. SUBCARINAL LYMPH NODE
- C. HILAR LYMPH NODE, CPC
- D. ANTERIOR PULMONARY LIGAMENT LYMPH NODE
- E. PROXIMAL BRONCHIAL LYMPH NODE
- F. LEFT UPPER LOBE OF LUNG, FPC

===== PRE-OPERATIVE DIAGNOSIS: =====

Left lung mass

===== POST-OPERATIVE DIAGNOSIS: =====

Same, pending pathology

===== CLINICAL INFORMATION: =====

Left lung mass, ? cancer; nonsmoker

===== INTRAOPERATIVE CONSULTATION: =====

CPC DIAGNOSIS: (Gross) received is one red-black lymph node (cross sections, cytospins x2) metastatic adenocarcinoma in lymph node," by [REDACTED]

FPC DIAGNOSIS: Received is a lung lobe with palpable mass in hilum, inked; (cross sections) gray-tan mass, about 1.5 cm from bronchial edge; (F/S) margin clear; small portion of tumor given to Fairfax tumor registry," by Dr [REDACTED]

===== GROSS DESCRIPTION: =====

- A. Received in formalin is a 1.2 x 0.5 x 0.3 cm gray-black lymph node. On sectioning, the cut surface is smooth. The specimen is entirely submitted in one cassette.
- B. Received in formalin is a single gray-black lymph node, measuring 0.7 x 0.5 x 0.2 cm. The specimen is bisected to reveal a smooth, gray-black cut surface. The specimen is entirely submitted in one cassette.
- C/CPC. Received is a previously bisected gray-black lymph node, measuring 1.0 x 1.0 x 0.5 cm. The cut surface is gray-black and finely granular, with tan-white foci. The specimen is entirely submitted in one cassette.
- D. Received in formalin is a 1.0 x 0.5 x 0.4 cm gray-tan cauterized lymph node. On sectioning, the cut surface is gray-black and smooth. The specimen is entirely submitted in one cassette.
- E. Received in formalin is a single red-tan, partially cauterized lymph node, measuring 1.0 x 0.5 x 0.3 cm. On sectioning, the cut surface is tan with

[page 2 of 3]
[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

F. Received in formalin is a left upper lobe of lung, weighing 165 grams and measuring 22 cm from superior to inferior, 13 cm from anterior to posterior, and 4.0 cm from medial to lateral. There are two stapled margins at the hilum, measuring 2.0 cm and 3.0 cm in length. The bifurcation portion of bronchus is present at the hilum, measuring 1.5 cm in diameter x 0.7 cm in length. Three stapled vessels are also present at the hilum, ranging from 0.2 to 0.3 cm in diameter. The stapled margins are trimmed and inked green. The hilar tissue is inked black. The pleural surface is pink-tan, smooth, and glistening, with minimal anthracotic pigmentation. On sectioning, an ill-circumscribed mass is present at the hilum, measuring 2.5 x 2.0 x 1.5 cm. The mass is composed of firm, gray-tan, focally black, and slightly granular tissue. The mass comes to within 0.1 cm of the inked hilar tissue, 0.5 cm of the inked pleural surface, and 1.5 cm of the bronchial and vascular resection margins. On opening the portions of bronchus, the lumina are smooth, without obvious involvement by lesion. The surrounding vessels are slightly compressed; however, on opening, the lumina are smooth, tan-white, and otherwise unremarkable. The lesion comes to within 1.5 cm of the inked stapled margin. Seven gray-black to tan-white firm lymph nodes are identified in the hilar region, ranging from 0.3 to 1.5 cm in greatest dimension. The remaining parenchyma is pink-tan to red and normally crepitant. The remaining intraparenchymal bronchi and vessels are unremarkable. No additional lesions or lymph nodes are identified. Representative sections are submitted in ten cassettes as follows: cassette 1 - bronchial and vascular margins; cassette 2 - two lymph nodes (one inked blue); cassette 3 - one trisected lymph node; cassettes 4 through 6 - mass (hilar structures in cassettes 4 and 5, inked pleura in cassette 6); cassette 7 - four lymph nodes; cassette 8 - uninvolved apical segment; cassette 9 - hilar region with green-inked margin; cassette 10 - superior lingular segment.

cassette.

A - F/FPC. Serial sections in sixteen slides are examined. In specimens A-F/FPC a total of twelve lymph nodes are identified, ten of which are microscopically or extensively involved by metastatic carcinoma. Only the aortopulmonary node (part A) and the anterior pulmonary ligament lymph node (part D) are free of tumor; the subcarinal lymph node (part B), the hilar lymph node (part C/CPC) and all hilar lymph nodes as well as proximal bronchial lymph nodes are involved by carcinoma. The tumor is a moderately-poorly differentiated adenocarcinoma, histologically consistent

[page 3 of 3]
[REDACTED]

Not for Permanent Storage in Medical Records / Not Valid for Signing

Patient
MRN
Date of Service
Performing Facility
Ordering Provider
Result Provider
Report Name

Requested by [REDACTED]

[REDACTED]
Surgical Report

with pulmonary origin. Tumor infiltrates to within 1 mm of the inked hilar pleural surface in block F4. The bronchial and vascular margins are technically free of tumor; however, minute tumor emboli are noted within lymphatic spaces of bronchial margin just deep to the intra-operative consult block; technically, lymphovascular invasion is not considered grounds for a true "positive" margin. It should be noted that the remainder of the resection specimen shows extensive lymphovascular invasion through grossly uninvolved lung; lymphovascular tumor emboli are also present in subpleural lymphatics, best seen in block F-9.

===== FINAL DIAGNOSIS: =====

A - F/FPC. LUNG, LEFT UPPER LOBE, LOBECTOMY WITH REGIONAL LYMPH NODE

DISSECTION AND BIOPSIES:

1. TUMOR TYPE: ADENOCARCINOMA
2. HISTOLOGIC GRADE: G2-3, MODERATELY-POORLY DIFFERENTIATED
3. MAXIMUM TUMOR SIZE (GROSS): 2.5 X 2.0 CM
4. EXTENT OF INVASION: pT1
5. REGIONAL LYMPH NODES: pN2, TEN OF TWELVE LYMPH NODES INVOLVED BY METASTATIC CARCINOMA INCLUDING SUBCARINAL LYMPH NODE (PART B)
6. DISTANT METASTASIS: pMX
7. MARGINS: ALL NEGATIVE (BRONCHIAL, VASCULAR, PLEURAL); INFILTRATING CARCINOMA APPROACHES TO WITHIN LESS THAN 1 MM OF INKED HILAR PLEURAL SURFACE
8. DIRECT EXTENSION OF TUMOR: NOT PRESENT
9. VENOUS (LARGE) VESSEL INVASION: NOT PRESENT
10. LYMPHATIC (SMALL) VESSEL INVASION: PRESENT, EXTENSIVE IN LUNG, INCLUDING SUBPLEURAL LYMPHATICS
11. ADDITIONAL PATHOLOGIC FINDINGS: NONE SIGNIFICANT

A-MALIGNANT

[REDACTED]

Source: NCI Genomic Data Commons file bd0b3f49-170d-49ae-a400-3733b73b3d5a (TCGA-55-6981.84738CAD-3B17-456C-A9A0-21F6E044A688.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).